Gene-level copy-number profile of tumor specimen TCGA-DX-A23Y-01A from TCGA case TCGA-DX-A23Y, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 80.1 years (29,272 days).
Specimen TCGA-DX-A23Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.11967ba0-a030-4a07-9576-03f774e89959.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A23Y-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d406551d-1111-4b79-b85f-82e31c4bf6f9

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 35; copy number 1: 1,671; copy number 2: 12,494; copy number 3: 18,690; copy number 4: 20,763; copy number 5: 2,616; copy number 6: 1,578; copy number 7: 556; copy number 8: 262; copy number 9: 291; copy number 10: 164; copy number 11: 32; copy number 12: 97; copy number 13: 10; copy number 14: 2; copy number 15: 132; copy number 16: 9; copy number 17: 15; copy number 18: 9; copy number 19: 33; copy number 20: 7; copy number 22: 3; copy number 23: 78; copy number 24: 9; copy number 25: 64; copy number 26: 39; copy number 27: 41; copy number 28: 3; copy number 30: 28; copy number 33: 24; copy number 36: 4; copy number 37: 5; copy number 38: 1; copy number 39: 5; copy number 40: 29; copy number 44: 5; copy number 47: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A23Y-01A-11D-A27O-01): tumor purity 0.55, ploidy 3.46, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:115,128,218–115,951,491, 21 genes: AP003179.1, CADM1, AP000465.1, AP000462.3, AP000462.1, AP000462.2, AP003174.2, AP003174.3, RPL12P46, AP003174.1, AP000997.1, AP000997.2, AP000997.3, AP000997.4, LINC02698, AP002991.1, AP002991.2, LINC00900, LINC02703, AP000797.2, AP000797.1.
- chr11:127,940,913–128,943,399, 14 genes: DNAJB6P1, LINC02725, LINC02098, ETS1, MIR6090, ETS1-AS1, AP001122.1, FLI1, SENCR, KCNJ1, AP000920.1, KCNJ5, C11orf45, TP53AIP1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,140 genes in 53 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:142,145,454–142,723,881, 14 genes, copy number 9: RNU6-425P, GK5, XRN1, RNU6-1294P, RNU1-100P, ATR, AC109992.1, AC109992.2, RPL6P9, RNA5SP143, PLS1, PLS1-AS1, RN7SKP25, AC072028.1.
- chr6:30,066,709–30,161,211, 7 genes, copy number 16 (within-gene range 2–16): PPP1R11, RNF39, TRIM31, TRIM31-AS1, AL669914.1, TRIM40, TRIM10.
- chr6:35,342,558–35,556,264, 9 genes, copy number 18: PPARD, MKRN6P, FANCE, RPL10A, MIR7111, TEAD3, TULP1, AL033519.4, AL033519.3.
- chr6:37,543,553–43,075,095, 133 genes, copy number 15–33 (within-gene range 4–33) (broad region; genes not listed).
- chr6:43,671,202–45,377,953, 37 genes, copy number 15–20 (within-gene range 5–20): MRPS18A, AL136131.1, AL136131.2, VEGFA, AL136131.3, AL157371.2, LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2, AL109615.1, AL109615.4, MRPL14, TMEM63B, CAPN11, RN7SL811P, MYMX, SLC29A1, HSP90AB1, SLC35B2, MIR4647, NFKBIE, TMEM151B, AL353588.1, TCTE1, AARS2, SPATS1, CDC5L, MIR4642, AL136140.1, AL136140.2, AL133334.1, SUPT3H, NUDT19P4, AL138880.2, RBM22P4.
- chr6:55,434,373–55,875,590, 3 genes, copy number 22: HMGCLL1, AL590290.1, BMP5.
- chr6:77,650,274–80,557,189, 44 genes, copy number 9–25 (within-gene range 4–25): MEI4, AL121718.1, AL450327.1, IRAK1BP1, PHIP, AL356776.1, AL356776.2, HMGN3, HMGN3-AS1, AL355796.1, Y_RNA, LCAL1, AL355379.1, AL078601.1, AL078601.2, AL391840.1, DBIP1, LCA5, AL391840.3, AL391840.2, AL451064.1, AL451064.2, SH3BGRL2, LINC01621, AL132875.1, AL132875.3, AL132875.2, ELOVL4, AL133475.1, GAPDHP63, RPL35AP18, TTK, AL591135.2, AL591135.1, AK4P5, BCKDHB, AL359715.3, RPL17P25, AL359715.4, AL359715.1, AL359715.2, RPSAP72, AL596028.1, AL590824.1.
- chr6:83,512,534–85,499,058, 26 genes, copy number 11: PRSS35, SNAP91, AL136972.1, AL139232.1, RIPPLY2, CYB5R4, AL034347.1, LINC02857, MRAP2, CEP162, LINC01611, SMARCE1P2, TBX18, TBX18-AS1, AL590143.1, AL035694.1, AL109941.1, AL139806.1, AL122016.1, AL135903.1, KRT18P64, LINC02535, DUTP5, TPT1P6, NT5E, AL589666.2.
- chr6:91,390,313–93,677,954, 20 genes, copy number 11–27 (within-gene range 4–27): AL080284.1, MIR4643, CASC6, MTATP6P25, MTND4LP19, MTCO1P56, RN7SL415P, AL590635.1, AL590814.1, RPL5P19, U3, AL133457.1, AL359987.1, LINC02531, U3, ATF1P1, AL138731.1, COPS5P1, EPHA7, AL591519.1.
- chr6:94,163,920–94,447,179, 5 genes, copy number 30: AL157378.1, AL078595.1, AL078595.3, AL078595.2, MTCYBP36.
- chr6:103,866,023–104,528,158, 4 genes, copy number 19–23 (within-gene range 4–23): AL590608.1, R3HDM2P2, NPM1P10, AL357522.1.
- chr6:105,403,207–106,359,717, 12 genes, copy number 9: AL096794.1, LINC02836, Z97206.1, AL591518.1, RN7SKP211, PRDM1, ATG5, AL022067.1, U4, RN7SL47P, RNU6-344P, AL356859.1.
- chr6:111,483,511–118,317,676, 98 genes, copy number 23–26 (within-gene range 6–26) (broad region; genes not listed).
- chr6:118,934,770–123,685,323, 51 genes, copy number 19–27 (within-gene range 5–27): AL137009.1, FAM184A, Y_RNA, MIR548B, AL022722.2, MAN1A1, AL022722.1, RNU6-194P, AL078600.1, MIR3144, AL096854.1, RNU6-214P, RNA5SP215, COX6A1P3, AL357513.1, TBC1D32, RNU6-1286P, Y_RNA, AL139098.1, AL139098.2, GJA1, RNU4-35P, AL138729.1, RNU4-76P, RNU2-8P, AL603865.2, SLC25A5P7, RPL23AP48, AL603865.1, HMGB3P18, RNU1-18P, HSF2, Z99129.4, SERINC1, Z99129.1, PKIB, Z99129.3, Z99129.2, AL512283.2, AL512283.1, AL512283.3, RN7SL564P, FABP7, SMPDL3A, ATP5MGP2, AL591428.1, CLVS2, TRDN, TRDN-AS1, AL445259.1, AL133257.1.
- chr6:124,962,545–128,761,808, 49 genes, copy number 9–12: RNF217, TPD52L1, HDDC2, AL121938.1, AL450332.1, AL365259.1, LINC02523, HEY2, NCOA7, NCOA7-AS1, RN7SKP56, HINT3, RNA5SP216, TRMT11, PPP1R14BP5, AL356534.1, CENPW, MIR588, RNU6-200P, AL359535.1, PRELID1P1, RPS4XP9, AL035603.1, RSPO3, RNF146, ECHDC1, RNA5SP217, YWHAZP4, RPL5P18, AL590002.1, AL096711.1, KIAA0408, AL096711.2, SOGA3, C6orf58, AL592291.1, AL356432.1, AL356432.3, AL356432.2, LINC02536, THEMIS, MRPS17P5, PTPRK, PTPRK-AS1, AL034349.1, EEF1DP5, Y_RNA, AL080315.1, Y_RNA.
- chr6:129,576,132–131,063,322, 14 genes, copy number 10 (within-gene range 5–10): ARHGAP18, RPL5P21, AL451046.2, B3GALNT2P1, AL451046.1, TMEM244, L3MBTL3, AL355581.1, SAMD3, TMEM200A, Y_RNA, AL583803.1, SMLR1, EPB41L2.
- chr6:138,161,939–139,667,284, 28 genes, copy number 12: ARFGEF3, PBOV1, SMIM28, AL031003.1, MARCKSL1P2, HEBP2, NHSL1, MIR3145, AL391669.1, AL590617.1, AL590617.2, CCDC28A-AS1, CCDC28A, ECT2L, ACKR4P1, AL121834.1, REPS1, ABRACL, HECA, AL031772.1, AL158850.1, TXLNB, AL592429.2, AL592429.1, CITED2, LINC01625, ATP5PBP6, AL390205.1.
- chr9:130,265,882–131,558,620, 34 genes, copy number 10: HMCN2, RN7SL665P, ASS1, FUBP3, MIR6856, AL359092.2, PRDM12, EXOSC2, ABL1, AL359092.3, AL359092.1, QRFP, FIBCD1, AL161733.1, LAMC3, AL583807.1, AIF1L, NUP214, RNU6-881P, AL157938.2, AL157938.3, AL157938.1, FAM78A, AL157938.4, PLPP7, AL354855.1, PRRC2B, SNORD62A, SNORD62B, AL358781.1, POMT1, AL358781.2, UCK1, PRRT1B.
- chr12:52,565,782–52,703,524, 9 genes, copy number 24 (within-gene range 3–24): KRT74, KRT72, KRT73-AS1, KRT73, KRT128P, KRT2, KRT1, KRT77, AC055716.3.
- chr12:57,738,013–57,984,761, 23 genes, copy number 30 (within-gene range 3–30): TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2.
- chr12:62,139,999–62,235,515, 2 genes, copy number 27: AC078789.1, KLF17P1.
- chr12:68,642,519–69,699,476, 33 genes, copy number 26–40: ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3.
- chr12:69,901,918–70,443,923, 8 genes, copy number 15: PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P.
- chr12:74,248,637–74,283,669, 2 genes, copy number 12: AC090502.2, AC090502.1.
- chr12:75,020,969–75,984,015, 18 genes, copy number 9–38 (within-gene range 5–38): AC073525.1, KCNC2, CAPS2-AS1, CCNG2P1, CAPS2, AC092552.1, AC121761.2, GLIPR1L1, GLIPR1L2, GLIPR1, AC121761.1, KRR1, AC078923.1, AC022507.1, AC078820.2, RPL10P13, SNORA70, AC078820.1.
- chr12:79,341,205–79,690,964, 6 genes, copy number 13–33 (within-gene range 7–33): AC027288.3, MIR1252, AC027288.2, AC027288.1, NOP56P3, PAWR.
- chr12:82,673,070–83,172,740, 5 genes, copy number 12: AC091214.1, TMTC2, RNU6-977P, RPL6P25, AC090680.1.
- chr12:84,147,304–84,294,562, 3 genes, copy number 16–40: AC090679.3, AC090679.2, AC090679.1.
- chr12:86,599,578–90,889,917, 52 genes, copy number 9–47 (within-gene range 6–47): AC010196.1, AC079597.1, RPL23AP68, AC079598.4, CYCSP30, AC079598.2, MKRN9P, LINC02258, AC079598.1, AC079598.3, RPS4XP15, C12orf50, C12orf29, CEP290, RNA5SP364, AC091516.1, TMTC3, Y_RNA, KITLG, AC024941.2, RNU1-117P, AC024941.1, LINC02458, AC006199.1, RNU7-120P, MRPS6P4, DUSP6, AC024909.1, AC010201.3, AC010201.2, AC010201.1, POC1B, CENPCP1, POC1B-GALNT4, GALNT4, POC1B-AS1, AC025034.2, AC025034.1, ATP2B1, ATP2B1-AS1, AC009522.1, RNA5SP365, MRPL2P1, RNU6-148P, BRWD1P2, LINC02399, AC126178.1, LINC02392, LINC02822, AC084365.1, AC112481.2, AC112481.1.
- chr12:91,327,045–93,460,826, 40 genes, copy number 10: LINC02823, AC090016.1, AC126175.1, AC126175.2, AC025254.1, AC090049.2, LINC02404, AC090049.1, LINC01619, AC123512.1, AC025164.2, BTG1, AC025164.1, RPL21P106, Y_RNA, LINC02391, CLLU1-AS1, CLLU1, AC063949.2, LINC02397, AC063949.1, PLEKHG7, EEA1, AC026111.1, HNRNPA1P50, RNU6-1329P, LINC02413, AC138123.1, Y_RNA, AC021646.1, RPL41P5, AC138123.2, NACAP8, LINC02412, AC126172.1, AC124947.2, AC124947.1, NUDT4, UBE2N, Y_RNA.
- chr12:96,160,692–96,269,824, 4 genes, copy number 36: LINC02452, ELK3, AC008149.1, AC008149.2.
- chr12:99,985,045–101,486,997, 35 genes, copy number 12–44: AC078916.1, RPS4XP1, AC126474.1, UHRF1BP1L, AC126474.2, AC010203.2, GOLGA2P5, RN7SL176P, AC010203.1, MIR1827, ACTR6, DEPDC4, Y_RNA, SCYL2, SLC17A8, NR1H4, AC010200.1, GAS2L3, PIGAP1, ANO4, AC138360.1, AC063947.1, SNX5P2, SLC5A8, RNU6-768P, AC079953.1, UTP20, ARL1, AC063948.1, RNU6-1068P, RPS27P23, Y_RNA, RNU5E-5P, RNA5SP367, SPIC.
- chr12:115,717,725–115,886,137, 5 genes, copy number 37: RN7SL865P, AC009387.1, LINC02463, AC012157.1, AC012157.3.
- chr12:120,904,702–121,039,242, 7 genes, copy number 13: AC069214.1, CLIC1P1, RPL12P33, HNF1A-AS1, HNF1A, C12orf43, OASL.
- chr14:102,341,102–106,062,683, 200 genes, copy number 9 (broad region; genes not listed).
- chr15:94,455,469–94,600,821, 3 genes, copy number 9 (within-gene range 4–9): AC009432.2, LINC02852, AC009432.1.
- chr15:96,294,935–96,551,517, 14 genes, copy number 10: AC016251.1, NR2F2, MIR1469, AC103746.1, AC087477.2, TUBAP12, AC087477.5, AC087477.3, PGAM1P12, AC087477.1, AC087477.4, RN7SKP254, Metazoa_SRP, AC110588.1.
- chr16:48,244,300–48,850,015, 19 genes, copy number 9 (within-gene range 2–9): LONP2, UBA52P8, AC023818.1, SIAH1, Metazoa_SRP, AC026470.3, AC026470.1, MOCS1P1, N4BP1, AC026470.2, RPS2P44, AC023813.2, AC023813.1, AC007611.1, AC023813.3, AC023813.4, KLF8P1, RNU6-257P, AC023827.1.
- chr16:51,107,571–51,671,563, 11 genes, copy number 9: SOD1P2, SALL1, AC009166.1, AC087564.1, AC009166.2, AC137494.1, AC137527.1, UNGP1, AC007344.1, HNRNPA1P48, RN7SKP142.
- chr16:58,083,068–59,199,395, 37 genes, copy number 10 (within-gene range 2–10): Y_RNA, AC012182.1, CFAP20, AC026771.1, AC009107.2, CSNK2A2, AC009107.1, RN7SL645P, CCDC113, PRSS54, GINS3, RNU6-269P, AC009118.1, RNU6-1110P, AC009118.2, LINC02137, NDRG4, RNU6-103P, SETD6, CNOT1, AC009118.3, SNORA46, SNORA50A, SNORA50A, AC010287.1, SLC38A7, AC012183.1, GOT2, AC106793.1, RNU6-1155P, RN7SL143P, GEMIN8P2, RPL12P36, AC092378.1, Metazoa_SRP, RPS27P27, AC092121.1.

Autosomal genes at a single copy (total copy number 1): 1,297. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
